Surgical pathology report (de-identified scan), TCGA case TCGA-K1-A3PO, project TCGA-SARC (Sarcoma), tissue source site University of Pittsburgh, specimen TCGA-K1-A3PO-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Pelvic mass.

PROCEDURE: Cuploproctectomy/pelvic mass.

BIOHAZARD: Yes, Hep B.

SPECIFIC CLINICAL QUESTION: No.

OUTSIDE TISSUE DIAGNOSIS: No.

PRIOR MALIGNANCY: No.

CHEMORADIATION THERAPY: No.

ORGAN TRANSPLANT: No.

IMMUNOSUPPRESSION: No.

OTHER DISEASES: No.

CYTOGENETICS TESTS: No.

ICD-0-3

leiomyosarcoma, NOS 8890/3
Pth: Site: Pelvis, NOS (sarcoma) C49.5
CQCF: retroperitoneum C48.0

hw 3/15/12

FINAL DIAGNOSIS:

PART 1: URETER, LEFT, MARGIN -
NEGATIVE FOR MALIGNANCY.

PART 2: SOFT TISSUE, BLADDER, PROSTATE AND PELVIC MASS, EXCISION -
A. LOW-GRADE (GRADE I) LEIOMYOSARCOMA OF THE PELVIC SOFT TISSUE INVADING EXTENSIVELY INTO THE MUSCLE WALL OF URINARY BLADDER AND FOCALLY INTO THE PROSTATE. (see comment).
B. MARGINS FREE OF TUMOR.
C. MITOSES ARE RARE. NO NECROSIS SEEN.
D. NO ANGIOLYMPHATIC AND PERINEURAL INVASION SEEN.
E. TNM STAGE: pTb N0 Mx.
F. BLADDER: VON BRUN'S NESTS AND CYSTITIS CYSTICA.
G. PROSTATE: CHRONIC PROSTATITIS.
H. URETERS: RIGHT URETER ENCASED BY TUMOR. LEFT URETER NEGATIVE FOR MALIGNANCY.

PART 3: LYMPH NODE, LEFT PERIVESICAL, EXCISION -
ONE (1) LYMPH NODE, NEGATIVE FOR MALIGNANCY.

PART 4: LYMPH NODES, RIGHT PELVIC, EXCISION -
NINE (9) LYMPH NODES, ALL NEGATIVE FOR MALIGNANCY.

PART 5: LYMPH NODES, RIGHT COMMON ILIAC AND PERICERVICAL NODES, EXCISION -
TWO (2) LYMPH NODES IDENTIFIED, BOTH NEGATIVE FOR MALIGNANCY.

PART 6: LYMPH NODES, LEFT PELVIC, EXCISION -
EIGHT (8) LYMPH NODES IDENTIFIED, ALL NEGATIVE FOR MALIGNANCY.

PART 7: LYMPH NODES, LEFT COMMON ILIAC, EXCISION -
THREE (3) LYMPH NODES IDENTIFIED, ALL NEGATIVE FOR MALIGNANCY.

COMMENT:

The tumor is composed of monomorphic spindle cells with eosinophilic cytoplasm, cigar-shaped nuclei and stippled chromatin, perinuclear vacuoles. The spindle cells are arranged in both a vague storiform pattern and in short bundles. Mitoses are rare and difficult to find. There is no necrosis. Cells are mingled with lymphocytes. There are many areas of myxoid change. Despite the relatively bland appearance tumor infiltrates in between normal smooth muscle bundles of the bladder wall and focally into the prostate. The tumor also encases the left ureter and abuts the urothelium but does not disrupt it.

The tumor cells resemble smooth muscle cells, and the initial biopsy had revealed strong immunopositivity for desmin and actin and ckit and CD34 were negative. Whether the tumor is primary in the urinary bladder or pelvic soft tissue may be a moot point, however the striking infiltrative pattern and myxoid changes support the diagnosis of a leiomyosarcoma.

Additional immunohistochemical stains have been ordered and will be reported in an addendum.

Addendum

Immunostains reveal the tumor is immunopositive for Desmin and AMA and demonstrates less than 5% positivity with Ki-67, marker proliferation. The cytokeratin AE1/3 and S-100 were negative. The positive, negative and internal controls are appropriate. This supports the above diagnosis.

Source: NCI Genomic Data Commons file 94714cff-88c1-44f7-b330-80985a3f5fe3 (TCGA-K1-A3PO.92AF1003-F09A-4162-B60C-7A43190EFFE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).